Surgical pathology report (de-identified scan), TCGA case TCGA-5M-AATE, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Sao Paulo, specimen TCGA-5M-AATE-01A (Primary Tumor).

Date:

SPECIMEN: Ascending colon, cecum, terminal ileum, appendix
PROCEDURE: Right hemicolectomy with terminal ileectomy

MACROSCOPY

- The specimen measures 22.5 cm in length and 5.5 to 7.5 cm in diameter.
- The terminal ileum segment has a length of 4.5 cm and a diameter of 2.5 cm, with no identifiable macroscopic pathologic features.
- The cecum contains a vegetative, infiltrative, well delimited lesion, continuous to the lumen of the appendix and adjacent to the ileocecal valve, 5.5 cm away from the nearest surgical margin (ileal margin).
- The lesion measures 6.5 cm and penetrates the full thickness of the bowel wall and the two proximal thirds of the appendix.
- A number of lymph nodes were dissected from the pericolic fat; diameters ranging from 0.3 to 1.1 cm.

MICROSCOPIC EXAMINATION

- Moderately differentiated tubular adenocarcinoma of the cecum, with extension to the appendix;
- Microscopic tumor extension: tumor penetrates the full thickness of the cecum wall, extending to the pericolic fat;
- Perineural invasion: present;
- Lymph-vascular invasion: present;
- Moderate desmoplastic stromal reaction, with mild tumoral lymphocytic infiltrate.
- Surgical margins free of neoplastic involvement;
- Number of lymph nodes examined: 15;
- Number of lymph nodes involved: 0;
- Stage: T3a pN0.

PATHOLOGISTS

CKF
path Adenocarcinoma NOS 8140/3
CKF
Adenocarcinoma, tubular 8211/3
path
Site: Ascending colon C18.2
Cecum C18.0
JMS 5/21/14

Source: NCI Genomic Data Commons file 217daeab-ff4e-411b-aa21-42f627e2bd88 (TCGA-5M-AATE.759F9B5B-2E5C-49E6-8E9B-32B265D1BE73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).